Somatic mutation profile of tumor specimen TCGA-13-0717-01A (aliquot TCGA-13-0717-01A-01W-0371-08) from TCGA case TCGA-13-0717, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.9 years (20,042 days).
Specimen TCGA-13-0717-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a16b311-a4f5-460c-bd9d-6d1931433df9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0717-10B (Blood Derived Normal), aliquot TCGA-13-0717-10B-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efcef600-aa26-4081-a8a1-5fc3eb8e0e05

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731_736del p.G244_M246delinsV | In Frame Del (DEL) | VAF 44/49 reads (90%) | hotspot (GDC flag); catalogued as COSV53328557, COSV53345811; called by mutect2, pindel, varscan2
- TTN | c.49123A>G p.I16375V (on ENST00000591111; = p.I8951V on NM_003319.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | PolyPhen benign (0.127); catalogued as COSV60202310; called by muse, mutect2, varscan2
